Gene-level copy-number profile of tumor specimen ALCH-AEG3-TTP1-A from ALCHEMIST case ALCH-AEG3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.8 years (24,036 days).
Specimen ALCH-AEG3-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0d4b991f-eeb3-40d5-8acf-ee6411da94ec.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEG3-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/74800db4-a9bc-4b90-9f9a-e26b49d5cb5f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 2,077; copy number 2: 53,782; copy number 3: 2,531.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:98,385,801–98,386,584, 1 gene (within-gene range 0–2): RPS3AP26.
- chr7:149,890,739–149,909,704, 2 genes: AC092681.3, AC092681.1.
- chr9:130,902,438–130,939,286, 1 gene (within-gene range 0–2): FIBCD1.
- chr19:19,740,884–19,754,986, 3 genes: AC011477.6, AC011477.7, AC011477.5.
- chr20:62,332,487–62,332,557, 1 gene (within-gene range 0–1): MIR4758.
- chr22:35,717,872–35,729,483, 1 gene: APOL5.
- chr22:41,938,737–41,958,933, 2 genes: CENPM, LINC00634.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 909. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
